MMRF case MMRF_2676 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dd57fef6-3f65-4691-b9f8-7e5a57c5b43a

Demographics
Sex at birth: female; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.3 years (17,278 days); ISS stage: II; Days to last known disease status: 464 days (1.3 years); Days to last follow up: 464 days (1.3 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 180 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -19, day 464.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.3 mmol/L.
- Hemoglobin 5.58 mmol/L.
- Absolute Neutrophil 2.41 ×10⁹/L.
- Platelets 237 ×10⁹/L.
- Albumin 33 g/L.
- Creatinine 68.1 µmol/L.
- M Protein 4.86 g/dL.
- Beta 2 Microglobulin 0.25 µg/mL.
- Lactate Dehydrogenase 2.47 µkat/L.

Other clinical attributes
- Day -19: Weight: 64 kg; Height: 168 cm.

Biospecimens (2 samples)
- Sample MMRF_2676_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2676_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
